Gene-level copy-number profile of tumor specimen TARGET-10-PATPGE-09A from TARGET case TARGET-10-PATPGE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 19.7 years (7,204 days).
Specimen TARGET-10-PATPGE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.826310c2-34e8-54e1-8e10-dad37b1cc034.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATPGE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate.
https://portal.gdc.cancer.gov/files/1a0ced6a-f6a7-4b8f-9b9c-c043880def83

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 2,663; copy number 2: 57,511; copy number 3: 20; copy number 4: 4; copy number 5: 29.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,276,318, 5 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1.
- chr7:142,749,468–142,802,748, 21 genes: PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–21,996,013, 1 gene: AL449423.1.
- chr18:59,899,996–60,018,731, 8 genes: PMAIP1, AC107990.1, NFE2L3P1, RN7SL342P, ENTR1P1, AC090377.1, SINHCAFP2, RNU6-567P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 29 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 5 (within-gene range 2–5): AC244205.1.
- chr2:88,857,161–89,143,160, 27 genes, copy number 5: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20.
- chr10:46,233,885–46,273,557, 1 gene, copy number 5: ANTXRLP1.

Autosomal genes at a single copy (total copy number 1): 277. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
